Somatic mutation profile of tumor specimen TARGET-10-PAPAGB-09A (aliquot TARGET-10-PAPAGB-09A-01D) from TARGET case TARGET-10-PAPAGB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.0 years (2,930 days).
Specimen TARGET-10-PAPAGB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fbcd225-4c55-4639-adb4-d1ed85b46015.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAGB-10A (Blood Derived Normal), aliquot TARGET-10-PAPAGB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29a7e989-ae49-4705-a703-93d4ca1e69da

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Ins 2, Intron 2, 5'UTR 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV55878075, COSV55925758; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADAM33 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.211); catalogued as rs759205904, COSV62934027; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626del p.N209Ifs*9 | Frame Shift Del (DEL) | VAF 21/121 reads (17%) | catalogued as rs1295666772; called by mutect2, pindel, varscan2
- CYLC1 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV61410919; called by muse, mutect2, varscan2
- KCNH1 | c.2515C>T p.R839C (on ENST00000271751 / NM_172362.3; = p.R812C on NM_002238.4) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV55068411; called by muse, mutect2, varscan2
- RNF152 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as rs772487156; called by muse, mutect2, varscan2
- TP53 | c.912_916dup p.R306Lfs*41 | Frame Shift Ins (INS) | VAF 24/110 reads (22%) | catalogued as COSV53301060; called by pindel, varscan2
- TRPM4 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs752951205; called by muse, mutect2, varscan2
- UNC80 | c.5425G>A p.G1809R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55885478; called by muse, mutect2, varscan2
- HTATSF1 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIMA1 | c.192dup p.R65* | Frame Shift Ins (INS) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- PPP1R3E | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- RTL9 | c.1475C>T p.T492I | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- TMEM102 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF654 | c.2818C>A p.Q940K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CFAP251 | c.627A>G p.G209= | Silent (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- DHRS1 | c.699C>A p.G233= | Silent (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- EXT1 | c.1458G>A p.A486= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs765275156, COSV65484516; called by muse, mutect2
- LGMN | c.357C>T p.G119= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs779146369, COSV58403776; called by muse, mutect2, varscan2
- PLOD2 | c.1083A>G p.G361= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- VLDLR | c.2244C>T p.D748= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- EGLN3 | c.357+24C>T | Intron (SNP) | VAF 13/71 reads (18%) | catalogued as COSV51655863; called by muse, mutect2, varscan2
- FRK | c.-14C>A | 5'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- KRTAP2-3 | c.*26G>A | 3'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs1340783897, COSV66952562; called by muse, mutect2, varscan2
- TTC7B | c.1966+7465G>C | Intron (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
